Somatic mutation profile of tumor specimen TCGA-BR-8680-01A (aliquot TCGA-BR-8680-01A-11D-2394-08) from TCGA case TCGA-BR-8680, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 45.5 years (16,637 days).
Specimen TCGA-BR-8680-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0035050-be9a-49dc-9d71-e6f2e7d938f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8680-10A (Blood Derived Normal), aliquot TCGA-BR-8680-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01e5472d-3c49-459b-8fb0-ad548266f272

The open-access MAF lists 6,617 somatic variants for this specimen: 5,132 protein-altering or splice-affecting, 1,341 silent, 144 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4,547, Silent 1,341, Nonsense Mutation 467, Intron 57, Splice Site 56, RNA 43, Splice Region 34, 3'UTR 18, Frame Shift Ins 13, 5'Flank 12, 5'UTR 8, Frame Shift Del 8.

Variants (750 of 6,617; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.8005C>T p.R2669* | Nonsense Mutation (SNP) | VAF 78/226 reads (35%) | catalogued as rs549857076, CM050170, COSV52503066; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 18/69 reads (26%) | catalogued as rs137854568, CM910029, COSV57324169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 33/93 reads (35%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.6610C>T p.R2204* | Nonsense Mutation (SNP) | VAF 35/110 reads (32%) | catalogued as rs752654519, COSV57326468, COSV99965912; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATM | c.7792C>T p.R2598* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as rs138941496, CM960105, COSV53725297, COSV99588934; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATM | c.8287C>T p.R2763* | Nonsense Mutation (SNP) | VAF 46/208 reads (22%) | catalogued as rs876659872, CM080077, COSV53734668; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BCL10 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 44/106 reads (42%) | catalogued as rs121918314, COSV65353611; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BCS1L | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 32/98 reads (33%) | catalogued as rs770749420, COSV55306551; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CASR | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 70/225 reads (31%) | catalogued as rs1085307984, CM107259, COSV56134117; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHRNA4 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28931591, CM001964, COSV64718873; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CNGB3 | c.1432C>T p.R478* | Nonsense Mutation (SNP) | VAF 68/208 reads (33%) | catalogued as rs201320564, CM050557; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CNGB3 | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as rs768345097, CM050551, COSV60686900; ClinVar: likely pathogenic; called by muse, mutect2
- CUBN | c.489G>A p.K163= | Splice Region (SNP) | VAF 5/27 reads (19%) | catalogued as rs386833789, CS127835; ClinVar: likely pathogenic; called by mutect2, varscan2
- CYBB | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 86/102 reads (84%) | catalogued as rs886041192, CM960436, COSV66085069; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DIS3 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 26/89 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs139907646, COSV66705997; called by muse, mutect2, varscan2
- DOCK7 | c.3976C>T p.R1326* (on ENST00000635253 / NM_001367561.1; = p.R1295* on NM_033407.3) | Nonsense Mutation (SNP) | VAF 51/171 reads (30%) | catalogued as rs756535975, COSV52000387; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DPYD | c.2275C>T p.R759* | Nonsense Mutation (SNP) | VAF 36/122 reads (30%) | catalogued as rs759372918, CM147506, COSV64593779; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- DSG2 | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs371146201; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- DYSF | c.3113G>A p.R1038Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150877497, CM033374; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 39/120 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs760101437, COSV51785413, COSV51800797; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EZH2 | c.2218G>A p.E740K (on ENST00000460911 / NM_001203247.2; = p.E745K on NM_004456.5) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs397515548, CM1110546, COSV57447594, COSV57464742; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FAT1 | c.4880G>A p.R1627Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.34); PolyPhen benign (0.043); catalogued as rs767331775, COSV71672487; called by muse, mutect2, varscan2
- FBN1 | c.8326C>T p.R2776* | Nonsense Mutation (SNP) | VAF 55/155 reads (35%) | catalogued as rs137854466, CM940772, COSV57312804; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 15/54 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs200698994; called by muse, mutect2, varscan2
- GABRA1 | c.799C>A p.L267I | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs796052492, COSV50099369, COSV50100120; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- GLDC | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121964979, CM042356; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GNPTG | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 61/165 reads (37%) | catalogued as rs1555452081, COSV50189884; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IL2RG | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 23/31 reads (74%) | catalogued as rs1556331272, COSV52147730; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IL7R | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 23/84 reads (27%) | hotspot (GDC flag); catalogued as rs201559094, CM045175, COSV57405649; called by muse, mutect2, varscan2
- ING1 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | hotspot (GDC flag); catalogued as COSV58167363; called by muse, mutect2, varscan2
- IREB2 | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 26/89 reads (29%) | catalogued as rs779567692, COSV51921552; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 30/107 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- LGI1 | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 31/102 reads (30%) | catalogued as rs886039496, COSV65057736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LHCGR | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 38/139 reads (27%) | catalogued as rs121912524, CM960940, COSV54292419; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAP3K1 | c.3989C>T p.S1330L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1287268127, COSV68121509, COSV68122713; called by muse, mutect2, varscan2
- MTO1 | c.1504C>T p.R502C (on ENST00000370300 / NM_133645.3; = p.R477C on NM_012123.4) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1033653237, COSV64773356; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MTOR | c.7500T>G p.I2500M | Missense Mutation (SNP) | VAF 45/143 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1057519915, COSV63869436; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.2678C>T p.A893V | Missense Mutation (SNP) | VAF 48/79 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs727503254, CM122816, COSV62517667; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 29/105 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CB | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 38/104 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as rs1451809865, COSV56683754; called by muse, mutect2, varscan2
- POLE | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 75/237 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519945, COSV57676103, COSV57677068, COSV57683938; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- POLK | c.461G>A p.G154E | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749804502, COSV54033403; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PUS7 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 46/155 reads (30%) | catalogued as rs772282094, COSV62676291; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RD3 | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 77/138 reads (56%) | catalogued as rs786205148, CM130361, COSV65362080; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SAR1B | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as rs137853125, CM080523, COSV68391425; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.4547C>T p.S1516L (on ENST00000303395 / NM_001202435.3; = p.S1505L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs139300715, CM024310, CM1511239, COSV57665028; ClinVar: uncertain significance / likely benign / likely pathogenic; called by muse, varscan2
- SLC29A3 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 59/200 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397515429, CM125130, COSV64384792; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMCHD1 | c.415A>C p.N139H | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1135402739, COSV55253802; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TMEM126A | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 62/208 reads (30%) | catalogued as rs121434508, CM092006, COSV58735100; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TSC22D2 | c.2204C>A p.S735Y | Missense Mutation (SNP) | VAF 52/178 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62622374, COSV62622441; called by muse, mutect2, varscan2
- VPS13B | c.4846C>T p.R1616* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as rs752429062, COSV62137304; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.685T>C p.F229L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1300346393, COSV59384480; called by muse, mutect2
- A2ML1 | c.2774C>T p.A925V | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs868280801, COSV55287959; called by muse, mutect2, varscan2
- AACS | c.253A>G p.K85E | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.152); catalogued as COSV99907916; called by muse, mutect2
- AACS | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 73/223 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs376023356; called by muse, mutect2, varscan2
- AACS | c.2014T>G p.F672V | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.241); catalogued as COSV55535540; called by muse, mutect2, varscan2
- AADAC | c.454C>A p.H152N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1477964979, COSV51758676; called by muse, mutect2, varscan2
- AADACL4 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs375635678; called by muse, mutect2, varscan2
- AAK1 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV68642815; called by muse, mutect2
- AASDH | c.1202T>C p.V401A | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); catalogued as COSV52705248; called by muse, mutect2, varscan2
- AATF | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs368531596; called by muse, mutect2
- AATK | c.1213G>A p.E405K (on ENST00000326724 / NM_001080395.3; = p.E302K on NM_004920.2) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58686373; called by muse, mutect2, varscan2
- ABCA1 | c.6612A>C p.E2204D | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as rs760311331, COSV66064956; called by muse, mutect2, varscan2
- ABCA1 | c.3071G>A p.S1024N | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV66064959; called by muse, mutect2, varscan2
- ABCA10 | c.2003A>C p.K668T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV52220037; called by muse, mutect2, varscan2
- ABCA12 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.061); catalogued as rs773100250, COSV55953508; called by muse, mutect2, varscan2
- ABCA13 | c.2376A>C p.K792N | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as COSV70025596, COSV70027005; called by muse, mutect2, varscan2
- ABCA3 | c.826C>T p.L276F | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.78); catalogued as COSV57051373; called by muse, mutect2, varscan2
- ABCA4 | c.2086A>G p.I696V | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as COSV64672407; called by muse, mutect2, varscan2
- ABCA4 | c.1664A>G p.D555G | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1179239331, COSV64672414; called by muse, mutect2, varscan2
- ABCA5 | c.4645G>T p.E1549* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as COSV67016201; called by muse, mutect2, varscan2
- ABCA5 | c.339A>C p.K113N | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.09); catalogued as COSV67016205; called by muse, mutect2, varscan2
- ABCA6 | c.3711A>C p.Q1237H | Missense Mutation (SNP) | VAF 32/265 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV52636995; called by muse, mutect2, varscan2
- ABCA6 | c.3680G>A p.R1227Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as rs768418765, COSV52636930; called by muse, mutect2, varscan2
- ABCA6 | c.2383G>A p.E795K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs374410367; called by muse, mutect2, varscan2
- ABCA6 | c.564+2T>C p.X188_splice | Splice Site (SNP) | VAF 30/73 reads (41%) | catalogued as COSV52637029; called by muse, mutect2, varscan2
- ABCA7 | c.3233T>G p.L1078R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV54026711; called by muse, mutect2, varscan2
- ABCA8 | c.1936G>T p.V646L | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.38); catalogued as COSV52197450; called by muse, mutect2, varscan2
- ABCA9 | c.2557C>T p.R853C | Missense Mutation (SNP) | VAF 91/151 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs764738392, COSV60622460, COSV60628108; called by muse, mutect2, varscan2
- ABCB1 | c.3253C>T p.R1085W | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199943026, COSV55947837; called by muse, mutect2, varscan2
- ABCB1 | c.2689G>A p.A897T | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.614); catalogued as rs147487745; called by muse, mutect2
- ABCB1 | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55947856; called by muse, mutect2, varscan2
- ABCB10 | c.2204T>G p.F735C | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV60620401; called by muse, mutect2, varscan2
- ABCB10 | c.1232T>G p.L411R | Missense Mutation (SNP) | VAF 72/147 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60620412; called by muse, mutect2, varscan2
- ABCB10 | c.743G>T p.R248I | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60620421; called by muse, mutect2, varscan2
- ABCB11 | c.2338C>A p.L780I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.281); catalogued as COSV55587773, COSV55592169; called by muse, mutect2, varscan2
- ABCB11 | c.370A>G p.T124A | Missense Mutation (SNP) | VAF 88/247 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV55587790; called by muse, mutect2, varscan2
- ABCB4 | c.255T>G p.F85L | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.364); catalogued as COSV55933628; called by muse, mutect2
- ABCB5 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs368226947; called by muse, mutect2, varscan2
- ABCC11 | c.2522G>A p.R841Q | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.89); PolyPhen benign (0.01); catalogued as rs765218887, COSV62321119, COSV62322128; called by muse, mutect2, varscan2
- ABCC11 | c.76G>T p.D26Y | Missense Mutation (SNP) | VAF 69/188 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.448); catalogued as COSV62322138; called by muse, mutect2, varscan2
- ABCC12 | c.3434A>C p.Q1145P | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV60912706; called by muse, mutect2, varscan2
- ABCC12 | c.1060T>C p.S354P | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60912711; called by muse, mutect2, varscan2
- ABCC4 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.085); catalogued as rs1246870484, COSV65310949; called by muse, mutect2, varscan2
- ABCD1 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 132/160 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV54383955; called by muse, mutect2, varscan2
- ABCG1 | c.719T>C p.F240S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59202245; called by muse, mutect2, varscan2
- ABHD1 | c.8G>A p.S3N | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); catalogued as rs752426472, COSV53149069; called by muse, mutect2, varscan2
- ABHD10 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs759940383, COSV56324751, COSV99845102; called by muse, mutect2, varscan2
- ABHD18 | c.614C>T p.A205V (on ENST00000398965 / NM_001039717.2; = p.A78V on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66293430; called by muse, mutect2, varscan2
- ABHD3 | c.81C>A p.F27L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV56676050; called by muse, mutect2
- ABI1 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as rs757418866, COSV61014740; called by muse, mutect2
- ABI3BP | c.1876G>T p.D626Y | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.157); catalogued as COSV52532003, COSV52544958, COSV99425928; called by muse, mutect2, varscan2
- ABI3BP | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201046479, COSV52532017; called by mutect2, varscan2
- ABL1 | c.566A>G p.E189G | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as COSV100583771; called by muse, mutect2, varscan2
- AC090517.4 | c.712C>A p.L238I | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV50996215; called by muse, mutect2, varscan2
- AC090517.4 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.247); catalogued as rs774201353, COSV50996219; called by muse, mutect2, varscan2
- AC092442.1 | c.118G>T p.G40* | Nonsense Mutation (SNP) | VAF 23/111 reads (21%) | catalogued as COSV51525720; called by muse, mutect2, varscan2
- AC109583.1 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.334); catalogued as rs1191681298, COSV58405414; called by muse, mutect2, varscan2
- AC126283.2 | c.199T>C p.C67R | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67098182; called by muse, mutect2, varscan2
- AC134980.2 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as rs372526138, COSV60906853; called by mutect2, varscan2
- ACACB | c.1289A>G p.D430G | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV58131023; called by muse, varscan2
- ACACB | c.1337G>T p.R446I | Missense Mutation (SNP) | VAF 136/440 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV58128531; called by muse, varscan2
- ACACB | c.5552A>G p.D1851G | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV58131036; called by muse, mutect2, varscan2
- ACADM | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.611); catalogued as COSV63720044, COSV63720242; called by muse, mutect2, varscan2
- ACADSB | c.1203G>T p.E401D | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62550498; called by muse, mutect2, varscan2
- ACCSL | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs759197314, COSV66580697; called by muse, varscan2
- ACER3 | c.559T>G p.L187V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV53597973; called by muse, mutect2, varscan2
- ACIN1 | c.614A>C p.K205T | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV52974623; called by muse, mutect2, varscan2
- ACKR1 | c.797T>G p.V266G | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63672267; called by muse, mutect2, varscan2
- ACKR4 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 67/364 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1398393923, COSV51442163; called by muse, mutect2, varscan2
- ACLY | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.98); catalogued as rs1555633148, COSV61249908; called by muse, mutect2, varscan2
- ACMSD | c.136T>G p.F46V | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV51606294; called by muse, mutect2, varscan2
- ACRBP | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs150031699; called by muse, mutect2, varscan2
- ACSF2 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs781188170, COSV51971814; called by muse, mutect2, varscan2
- ACSL5 | c.1753G>A p.V585M (on ENST00000354273; = p.V641M on NM_016234.3) | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1374879428, COSV61129667; called by muse, varscan2
- ACSL5 | c.1834A>C p.N612H (on ENST00000354273; = p.N668H on NM_016234.3) | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.336); catalogued as COSV61129677; called by muse, varscan2
- ACSM1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs769122330, COSV54632818; called by muse, mutect2, varscan2
- ACSM1 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV54634196; called by muse, mutect2, varscan2
- ACSM2A | c.241T>C p.W81R (on ENST00000219054; = p.W2R on NM_001308169.2) | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.395); catalogued as rs1228705457, COSV54583407; called by muse, mutect2, varscan2
- ACSM2B | c.996G>T p.Q332H | Missense Mutation (SNP) | VAF 79/258 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV61657261; called by muse, mutect2, varscan2
- ACSM3 | c.132A>C p.E44D | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.335); catalogued as COSV56843591; called by muse, mutect2, varscan2
- ACSM4 | c.1163A>C p.K388T | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV68067315; called by muse, mutect2, varscan2
- ACTL10 | c.469A>G p.T157A | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV55775373; called by muse, mutect2
- ACTL7A | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 28/84 reads (33%) | catalogued as COSV61776434; called by muse, mutect2, varscan2
- ACTL8 | c.53G>A p.G18D | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64860890; called by muse, mutect2, varscan2
- ACTL8 | c.558G>T p.K186N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV64860896; called by muse, mutect2, varscan2
- ACTN2 | c.1263G>T p.E421D | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.887); catalogued as COSV63973599; called by muse, mutect2, varscan2
- ACTR3 | c.713T>C p.L238S | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV54299944; called by muse, mutect2, varscan2
- ACTR5 | c.856G>A p.G286S | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.21); catalogued as COSV54760252; called by muse, mutect2, varscan2
- ACTR8 | c.221T>G p.V74G | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV51635706; called by muse, mutect2, varscan2
- ACTRT1 | c.44A>G p.D15G | Missense Mutation (SNP) | VAF 87/115 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64419096; called by muse, mutect2, varscan2
- ACYP2 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as COSV57813242; called by muse, mutect2, varscan2
- ADAM11 | c.736A>G p.I246V | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52345255; called by muse, varscan2
- ADAM20 | c.2057A>C p.N686T | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV56454444; called by muse, mutect2, varscan2
- ADAM21 | c.443T>G p.I148S | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.105); catalogued as COSV50790158; called by muse, mutect2, varscan2
- ADAM22 | c.2552T>G p.F851C | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55973024; called by muse, mutect2, varscan2
- ADAMDEC1 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 84/154 reads (55%) | catalogued as rs376286647, COSV56474636; called by muse, mutect2, varscan2
- ADAMTS14 | c.2971C>T p.R991W | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750200846, COSV64600799; called by muse, mutect2, varscan2
- ADAMTS14 | c.3413C>T p.T1138M | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.226); catalogued as rs374312186; called by muse, mutect2
- ADAMTS15 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV54504143; called by muse, mutect2, varscan2
- ADAMTS16 | c.963+1G>A p.X321_splice | Splice Site (SNP) | VAF 4/37 reads (11%) | catalogued as rs1398018872, COSV99940804; called by muse, mutect2
- ADAMTS16 | c.2324G>A p.R775H | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs539873933, COSV56983275, COSV99941580; called by muse, mutect2, varscan2
- ADAMTS17 | c.2897C>T p.A966V | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV51476171; called by muse, mutect2, varscan2
- ADAMTS17 | c.1645T>C p.W549R | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV51476182; called by muse, mutect2, varscan2
- ADAMTS18 | c.2551A>G p.N851D | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51402003; called by muse, mutect2, varscan2
- ADAMTS18 | c.1145G>T p.R382I | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51402028; called by muse, mutect2, varscan2
- ADAMTS2 | c.3479C>T p.A1160V | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.253); catalogued as rs1225747635, COSV52370256; called by muse, mutect2, varscan2
- ADAMTS2 | c.2334G>T p.E778D | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV52370267; called by muse, mutect2, varscan2
- ADAMTS2 | c.518G>A p.S173N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV51074125; called by muse, mutect2, varscan2
- ADAMTS20 | c.4883G>A p.R1628Q | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs781368134, COSV67129283; called by muse, mutect2, varscan2
- ADAMTS20 | c.4718C>A p.S1573Y | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.254); catalogued as COSV67129290; called by muse, mutect2, varscan2
- ADAMTS20 | c.2179T>G p.F727V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV67129297; called by muse, mutect2, varscan2
- ADAMTS20 | c.1697G>A p.S566N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs147849669, COSV67132621; called by muse, mutect2, varscan2
- ADAMTS5 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1286298815, COSV53175922; called by muse, mutect2, varscan2
- ADAMTS6 | c.2077T>G p.C693G | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66858081; called by muse, mutect2, varscan2
- ADAMTS8 | c.1370G>T p.G457V | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57292408; called by muse, mutect2, varscan2
- ADAMTS9 | c.2531G>A p.R844H | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs148570059; called by muse, mutect2, varscan2
- ADAMTS9 | c.2249C>A p.S750Y | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55774786; called by muse, varscan2
- ADAMTSL2 | c.882G>T p.E294D | Missense Mutation (SNP) | VAF 118/372 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as COSV63203665; called by muse, mutect2
- ADAMTSL3 | c.190-1G>T p.X64_splice | Splice Site (SNP) | VAF 22/55 reads (40%) | catalogued as COSV54441473; called by muse, mutect2, varscan2
- ADARB1 | c.1694T>C p.V565A (on ENST00000360697 / NM_001346687.2; = p.V525A on NM_001112.4) | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV62343062; called by muse, mutect2, varscan2
- ADCY1 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as rs1382950758, COSV52032144; called by muse, mutect2, varscan2
- ADCY3 | c.2276T>C p.V759A | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV53165853; called by muse, mutect2, varscan2
- ADCYAP1 | c.488A>C p.K163T | Missense Mutation (SNP) | VAF 82/274 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV52485961; called by muse, mutect2
- ADGRB2 | c.1847C>T p.S616L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772109417, COSV57071911, COSV57076238; called by muse, mutect2, varscan2
- ADGRB3 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs549905059, COSV65389273, COSV65401985; called by muse, mutect2, varscan2
- ADGRE1 | c.1075G>A p.V359I | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs772948778, COSV51673784, COSV51677393; called by muse, mutect2, varscan2
- ADGRE3 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs779190370, COSV53729343; called by muse, mutect2, varscan2
- ADGRF1 | c.4A>C p.K2Q | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV64799744; called by muse, mutect2, varscan2
- ADGRF5 | c.3970A>C p.N1324H | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV51931740; called by muse, mutect2, varscan2
- ADGRG4 | c.6698C>T p.S2233L | Missense Mutation (SNP) | VAF 73/84 reads (87%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs567340291, COSV54952396; called by muse, mutect2, varscan2
- ADGRG4 | c.7174G>A p.A2392T | Missense Mutation (SNP) | VAF 51/66 reads (77%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as COSV54952404; called by muse, mutect2, varscan2
- ADGRG5 | c.1427C>A p.S476Y | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as COSV100446323, COSV61082872; called by muse, mutect2, varscan2
- ADGRG6 | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 57/212 reads (27%) | catalogued as rs777589148, COSV51589053; called by muse, mutect2, varscan2
- ADGRL2 | c.55T>G p.F19V | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV54658051; called by muse, mutect2, varscan2
- ADGRL2 | c.808G>T p.E270* | Nonsense Mutation (SNP) | VAF 55/135 reads (41%) | catalogued as COSV54659874, COSV54688856; called by muse, mutect2, varscan2
- ADGRL4 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as rs767685899, COSV66060741; called by muse, mutect2, varscan2
- ADGRL4 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs748635862, COSV66060729; called by muse, varscan2
- ADGRV1 | c.3420T>G p.I1140M | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV67981599; called by muse, mutect2, varscan2
- ADGRV1 | c.6778C>T p.R2260* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as rs779821643, COSV67977499; called by muse, mutect2, varscan2
- ADH5 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs773778500, COSV56447875, COSV99596150; called by muse, mutect2, varscan2
- ADH6 | c.1064A>C p.K355T | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV52955601; called by muse, mutect2, varscan2
- ADH6 | c.392T>G p.F131C | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV52955619; called by muse, mutect2, varscan2
- ADORA2A | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs199792438, COSV58378292, COSV58381201; called by muse, mutect2, varscan2
- AEBP1 | c.2831G>A p.R944Q | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56256444; called by muse, mutect2, varscan2
- AFAP1L1 | c.1637C>T p.S546F | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV57044518; called by muse, mutect2, varscan2
- AFF3 | c.3080C>A p.S1027Y | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57847756; called by muse, mutect2
- AFF3 | c.2224T>G p.F742V | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.688); catalogued as COSV57847766, COSV57879120; called by muse, mutect2, varscan2
- AFF4 | c.3436C>T p.R1146C | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755303727, COSV54793041; called by muse, mutect2, varscan2
- AFTPH | c.152A>G p.D51G | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.616); catalogued as COSV53216764; called by muse, varscan2
- AFTPH | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 35/98 reads (36%) | catalogued as COSV53215752; called by muse, mutect2, varscan2
- AFTPH | c.896T>C p.V299A | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV53216808; called by muse, mutect2, varscan2
- AGA | c.889T>G p.F297V | Missense Mutation (SNP) | VAF 66/199 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV52805970; called by muse, mutect2, varscan2
- AGAP1 | c.590A>C p.K197T | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV58321543; called by muse, mutect2, varscan2
- AGAP3 | c.1633A>C p.K545Q (on ENST00000622464; = p.K581Q on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68243867; called by muse, mutect2, varscan2
- AGBL1 | c.334C>A p.L112I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.482); catalogued as rs778991414, COSV69795627; called by mutect2, varscan2
- AGBL1 | c.1490A>C p.K497T | Missense Mutation (SNP) | VAF 56/179 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.073); catalogued as COSV66853291; called by muse, varscan2
- AGBL4 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748307842, COSV61891203; called by muse, mutect2, varscan2
- AGBL5 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs751461917, COSV59936080; called by muse, mutect2, varscan2
- AGER | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs766063160, COSV61247266; called by muse, mutect2, varscan2
- AGGF1 | c.1218G>A p.W406* | Nonsense Mutation (SNP) | VAF 38/152 reads (25%) | catalogued as COSV57228366; called by muse, mutect2
- AGO3 | c.1592C>T p.A531V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV55792224; called by muse, mutect2, varscan2
- AGO4 | c.1685A>G p.K562R | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV64616699; called by muse, mutect2, varscan2
- AGTR2 | c.1061C>A p.S354Y | Missense Mutation (SNP) | VAF 100/128 reads (78%) | SIFT tolerated (1); PolyPhen benign (0.271); catalogued as COSV64156282, COSV64156491; called by muse, mutect2, varscan2
- AGXT2 | c.560A>G p.N187S | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as COSV51484995; called by muse, mutect2, varscan2
- AGXT2 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs867649192, COSV51485009; called by muse, varscan2
- AHDC1 | c.2182C>T p.R728W | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); catalogued as rs201595662; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHI1 | c.2269C>A p.H757N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.992); catalogued as COSV55625468; called by muse, mutect2, varscan2
- AHNAK2 | c.11011G>A p.D3671N | Missense Mutation (SNP) | VAF 84/275 reads (31%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.866); catalogued as rs756916033, COSV60911380; called by muse, mutect2
- AHR | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54121955; called by muse, mutect2, varscan2
- AHR | c.1738G>T p.E580* | Nonsense Mutation (SNP) | VAF 62/170 reads (36%) | catalogued as COSV54122406; called by muse, mutect2, varscan2
- AHSP | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100176244; called by muse, mutect2, varscan2
- AHSP | c.191A>G p.D64G | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as rs889130773, COSV100176245; called by muse, mutect2, varscan2
- AIFM3 | c.35A>C p.E12A | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV58998315; called by muse, mutect2, varscan2
- AIM2 | c.85C>A p.L29I | Missense Mutation (SNP) | VAF 83/169 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as COSV104426654, COSV63698971; called by muse, mutect2, varscan2
- AK9 | c.5537T>G p.F1846C | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV69850083; called by muse, mutect2
- AK9 | c.5318C>T p.S1773L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1386474497, COSV69849868; called by muse, mutect2, varscan2
- AK9 | c.5030C>A p.S1677Y | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs746816252, COSV69850091; called by muse, mutect2, varscan2
- AKAP10 | c.1358T>G p.F453C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56730581; called by muse, mutect2, varscan2
- AKAP12 | c.3006G>T p.M1002I | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV53572462; called by muse, mutect2, varscan2
- AKAP13 | c.3210G>T p.K1070N | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as COSV63452409; called by muse, mutect2, varscan2
- AKAP3 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs764368886, COSV57415228, COSV57418275; called by muse, mutect2, varscan2
- AKAP6 | c.2272T>G p.S758A | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV55208911; called by muse, mutect2, varscan2
- AKAP6 | c.6835G>T p.D2279Y | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.188); catalogued as COSV55208917; called by muse, mutect2, varscan2
- AKAP9 | c.2831A>C p.K944T | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62342010; called by muse, mutect2, varscan2
- AKAP9 | c.5149T>G p.L1717V | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV62342023; called by muse, mutect2, varscan2
- AKAP9 | c.6881C>T p.A2294V (on ENST00000359028; = p.A2270V on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.045); catalogued as COSV62342049; called by muse, mutect2, varscan2
- AKAP9 | c.7065A>G p.I2355M (on ENST00000359028; = p.I2331M on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV62342064; called by muse, mutect2, varscan2
- AKIRIN2 | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 41/102 reads (40%) | catalogued as COSV57636251, COSV57637151; called by muse, mutect2, varscan2
- AKNAD1 | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs745341212, COSV62196741; called by muse, mutect2, varscan2
- AKR1C4 | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54122838; called by muse, mutect2, varscan2
- AKR1D1 | c.345T>G p.D115E | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54336887; called by muse, varscan2
- AKTIP | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV50874331; called by muse, mutect2, varscan2
- AL592490.1 | c.1807G>T p.E603* | Nonsense Mutation (SNP) | VAF 34/93 reads (37%) | catalogued as COSV69425355, COSV69427187; called by muse, mutect2, varscan2
- ALB | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs78575701, CM984718, COSV104405337, COSV55736801, COSV55738814; ClinVar: not provided; called by muse, mutect2, varscan2
- ALB | c.1774T>G p.F592V | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55736808; called by muse, mutect2, varscan2
- ALDH1A2 | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs781766424, COSV51079141; called by muse, mutect2, varscan2
- ALDH1A3 | c.439T>C p.W147R | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60901262; called by muse, mutect2, varscan2
- ALDH1L2 | c.462T>G p.F154L | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.246); catalogued as COSV51554470; called by muse, mutect2, varscan2
- ALDH9A1 | c.973C>A p.L325I | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV61339444; called by muse, mutect2, varscan2
- ALG11 | c.154T>A p.L52I | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.031); catalogued as rs746211021, COSV101584267; called by muse, mutect2, varscan2
- ALG13 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 301/370 reads (81%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.604); catalogued as rs767326994, COSV52636707; called by muse, mutect2, varscan2
- ALG5 | c.750T>G p.F250L | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV53504798; called by muse, mutect2, varscan2
- ALG6 | c.370T>C p.Y124H | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54764246; called by muse, mutect2, varscan2
- ALK | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as rs759426382, COSV66562464; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALKAL1 | c.228C>A p.F76L | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.343); catalogued as COSV62130126; called by muse, mutect2, varscan2
- ALLC | c.359A>C p.E120A | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as COSV52993672; called by muse, mutect2, varscan2
- ALMS1 | c.387A>C p.Q129H | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs746391155, COSV52506333; called by muse, mutect2, varscan2
- ALMS1 | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 81/254 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV52506342; called by muse, mutect2, varscan2
- ALMS1 | c.7103G>A p.S2368N | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs781640600, COSV52506353; called by muse, mutect2, varscan2
- ALMS1 | c.9955A>C p.T3319P | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52506365; called by muse, mutect2, varscan2
- ALMS1 | c.11668+2T>G p.X3890_splice | Splice Site (SNP) | VAF 65/174 reads (37%) | catalogued as COSV52506374; called by muse, mutect2, varscan2
- ALOX12B | c.1118A>G p.D373G | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59871975; called by muse, mutect2, varscan2
- ALOX15B | c.1334A>G p.N445S | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV66479219; called by muse, mutect2, varscan2
- ALOXE3 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs768303204, COSV58554580; called by muse, mutect2, varscan2
- ALPK2 | c.3982C>A p.L1328I | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.131); catalogued as COSV100864282, COSV64491985; called by muse, mutect2, varscan2
- AMER1 | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 39/67 reads (58%) | catalogued as COSV57657110, COSV57662413; called by muse, mutect2, varscan2
- AMIGO3 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.94); PolyPhen benign (0.047); catalogued as rs767368457, COSV57538009; called by muse, mutect2, varscan2
- AMN1 | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV55670827; called by muse, mutect2, varscan2
- AMOTL1 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs774054686, COSV58565690; called by muse, mutect2, varscan2
- AMPD1 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs374697989, COSV62415501; called by muse, mutect2, varscan2
- AMPD1 | c.1710G>T p.K570N | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as rs1354451905, COSV62415508; called by muse, mutect2, varscan2
- AMPH | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781682680, COSV57737654; called by muse, mutect2, varscan2
- AMTN | c.146C>A p.P49H | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV59488644; called by muse, varscan2
- AMZ2 | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 29/94 reads (31%) | catalogued as COSV63082654; called by muse, mutect2, varscan2
- ANAPC1 | c.2672A>C p.E891A | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.107); catalogued as COSV61975102; called by muse, mutect2, varscan2
- ANGPTL2 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.734); catalogued as rs770228069, COSV52218903; called by muse, mutect2, varscan2
- ANK2 | c.10804C>T p.R3602* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as COSV52152721; called by muse, mutect2, varscan2
- ANK3 | c.8696C>T p.S2899F | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV55045136; called by muse, varscan2
- ANKAR | c.3529G>A p.E1177K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs781375783, COSV55610933; called by muse, mutect2, varscan2
- ANKAR | c.4264A>G p.K1422E | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.027); catalogued as COSV51462066; called by muse, mutect2, varscan2
- ANKDD1A | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.809); catalogued as rs768567148, COSV60353086; called by muse, mutect2, varscan2
- ANKDD1A | c.770A>C p.K257T | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.696); catalogued as COSV60353096; called by muse, mutect2, varscan2
- ANKEF1 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 54/179 reads (30%) | catalogued as rs774211930, COSV65691928; called by muse, mutect2, varscan2
- ANKFY1 | c.3379C>T p.R1127C (on ENST00000341657 / NM_001330063.2; = p.R1128C on NM_016376.5) | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58915905; called by muse, mutect2, varscan2
- ANKFY1 | c.2089G>A p.A697T (on ENST00000341657 / NM_001330063.2; = p.A698T on NM_016376.5) | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV58915914; called by muse, mutect2, varscan2
- ANKLE2 | c.1835C>A p.A612D | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.408); catalogued as COSV61708500; called by muse, mutect2, varscan2
- ANKMY2 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 25/97 reads (26%) | catalogued as COSV61011323; called by muse, mutect2, varscan2
- ANKRD1 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.384); catalogued as rs1293523344, COSV65467209; called by muse, mutect2
- ANKRD11 | c.4196C>T p.A1399V | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.196); catalogued as rs752446167, COSV56357951; called by muse, mutect2, varscan2
- ANKRD12 | c.2436A>C p.E812D | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.978); catalogued as COSV50820964; called by muse, varscan2
- ANKRD13C | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as rs1461634372, COSV52030719; called by muse, mutect2, varscan2
- ANKRD16 | c.877C>A p.L293I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51947075; called by muse, mutect2, varscan2
- ANKRD17 | c.4374T>G p.I1458M | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58217809; called by muse, mutect2, varscan2
- ANKRD22 | c.536A>C p.K179T | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as COSV64236113; called by muse, mutect2, varscan2
- ANKRD26 | c.3513T>G p.F1171L | Missense Mutation (SNP) | VAF 62/200 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.441); catalogued as COSV65774688; called by muse, mutect2, varscan2
- ANKRD26 | c.1168T>G p.L390V | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.395); catalogued as COSV65793538; called by muse, mutect2, varscan2
- ANKRD26 | c.742C>A p.L248I | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.098); catalogued as COSV65793542; called by muse, mutect2, varscan2
- ANKRD30A | c.689A>G p.D230G (on ENST00000611781; = p.D174G on NM_052997.2) | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs753172655, COSV64607014; called by muse, mutect2, varscan2
- ANKRD30A | c.2046A>C p.E682D (on ENST00000611781; = p.E626D on NM_052997.2) | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.585); catalogued as COSV64607024; called by muse, mutect2, varscan2
- ANKRD30A | c.2816T>C p.V939A (on ENST00000611781; = p.V883A on NM_052997.2) | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1455239231, COSV64607037; called by muse, mutect2, varscan2
- ANKRD36B | c.1415T>C p.V472A | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV51531273; called by muse, mutect2, varscan2
- ANKRD42 | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV52614851, COSV52615086; called by muse, mutect2, varscan2
- ANKRD45 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 29/165 reads (18%) | catalogued as COSV100322674, COSV60960562; called by muse, mutect2, varscan2
- ANKRD52 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 80/270 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as COSV57283325; called by muse, mutect2, varscan2
- ANKRD6 | c.562T>C p.S188P | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.022); catalogued as COSV60230092; called by muse, mutect2, varscan2
- ANKRD9 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV54601719; called by muse, mutect2, varscan2
- ANLN | c.52A>C p.N18H | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56074807; called by muse, mutect2, varscan2
- ANLN | c.442A>C p.K148Q | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as COSV56074815; called by muse, mutect2, varscan2
- ANLN | c.2762A>C p.H921P | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV56074823; called by muse, mutect2, varscan2
- ANO4 | c.628C>T p.R210W (on ENST00000392977 / NM_001286615.2; = p.R175W on NM_178826.4) | Missense Mutation (SNP) | VAF 129/405 reads (32%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.719); catalogued as rs372521580; called by muse, mutect2, varscan2
- ANO5 | c.2023G>T p.E675* | Nonsense Mutation (SNP) | VAF 46/166 reads (28%) | catalogued as COSV61083466; called by muse, mutect2, varscan2
- ANO6 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs745465915, COSV57657217; called by muse, mutect2, varscan2
- ANO7 | c.1733G>A p.R578H (on ENST00000274979; = p.R524H on NM_001370694.2) | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs778300142, COSV51468501, COSV51469706; called by muse, mutect2, varscan2
- ANP32E | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 39/143 reads (27%) | catalogued as COSV100029753, COSV58481613; called by muse, mutect2, varscan2
- ANPEP | c.2128G>T p.D710Y | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV55590310; called by muse, mutect2, varscan2
- ANTXR1 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58011180; called by muse, mutect2, varscan2
- ANTXR2 | c.304A>C p.I102L | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV55017262; called by muse, mutect2, varscan2
- AP002512.3 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as rs749473920, COSV54405969; called by muse, mutect2, varscan2
- AP1G1 | c.540A>C p.K180N | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV55487183; called by muse, mutect2, varscan2
- AP1G2 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs566425276, COSV55337743; called by muse, mutect2, varscan2
- AP3B1 | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs907819185, COSV54880515; called by muse, mutect2, varscan2
- AP3B2 | c.155C>A p.S52Y | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV55607847, COSV55607962; called by muse, mutect2, varscan2
- AP4B1 | c.1616A>G p.D539G | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV56724050; called by muse, mutect2, varscan2
- APBA1 | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV55224755; called by muse, mutect2, varscan2
- APBA2 | c.2104G>A p.E702K | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1567033604, COSV68788716; called by muse, mutect2, varscan2
- APBB2 | c.2006T>G p.F669C (on ENST00000295974 / NM_001166050.2; = p.F670C on NM_004307.2) | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55949705; called by muse, mutect2, varscan2
- APC | c.2330A>G p.D777G | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV57333746; called by muse, mutect2, varscan2
- APC | c.3625G>T p.E1209* | Nonsense Mutation (SNP) | VAF 50/124 reads (40%) | catalogued as CD011096, COSV57327136; called by muse, mutect2, varscan2
- APC2 | c.357C>A p.S119R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV52017039; called by muse, mutect2, varscan2
- APC2 | c.2816G>A p.R939H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV52017055; called by muse, mutect2, varscan2
- APCDD1 | c.1537C>T p.R513C | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs754328837, COSV62372276; called by muse, mutect2, varscan2
- APH1B | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs551566250, COSV56013895; called by muse, mutect2, varscan2
- APLF | c.881A>G p.N294S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV58143648; called by muse, mutect2, varscan2
- APLNR | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.165); catalogued as COSV57241883; called by muse, mutect2, varscan2
- APOA4 | c.239T>G p.L80R | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.188); catalogued as COSV63360240; called by muse, mutect2, varscan2
- APOB | c.10645A>C p.N3549H | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as COSV51929410, COSV51956782; called by muse, mutect2, varscan2
- APOB | c.7945G>A p.E2649K | Missense Mutation (SNP) | VAF 81/260 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.535); catalogued as COSV51925442; called by muse, mutect2, varscan2
- APOB | c.6170T>G p.F2057C | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.784); catalogued as COSV51929435; called by muse, mutect2, varscan2
- APOB | c.3425C>T p.S1142L | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs199859104, COSV51929457; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOB | c.2817C>A p.G939= | Splice Region (SNP) | VAF 25/83 reads (30%) | catalogued as COSV51929471; called by muse, mutect2, varscan2
- APOH | c.807A>C p.K269N | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV52771920; called by muse, mutect2
- APPL1 | c.99T>G p.I33M | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV55700233; called by muse, mutect2, varscan2
- APPL1 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as rs764670150, COSV55700245; called by muse, mutect2, varscan2
- AQR | c.399A>C p.E133D | Missense Mutation (SNP) | VAF 92/305 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV50030950; called by muse, mutect2, varscan2
- ARCN1 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs367554879; called by muse, mutect2, varscan2
- ARFGEF1 | c.4493G>A p.R1498Q | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); catalogued as COSV51605270; called by muse, mutect2, varscan2
- ARFGEF1 | c.557A>C p.K186T | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV51605286; called by muse, mutect2, varscan2
- ARFGEF2 | c.1475C>A p.S492Y | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64211331, COSV64213467; called by muse, mutect2, varscan2
- ARFGEF3 | c.4841C>T p.A1614V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs767280503, COSV52453788; called by muse, mutect2, varscan2
- ARFIP2 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs185626181, COSV99601537; called by muse, mutect2, varscan2
- ARGLU1 | c.781T>C p.S261P | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV65608063; called by muse, mutect2, varscan2
- ARHGAP11A | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1001829788, COSV100853215; called by mutect2, varscan2
- ARHGAP15 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.396); catalogued as COSV54485463; called by muse, mutect2, varscan2
- ARHGAP28 | c.1604T>G p.I535S (on ENST00000383472 / NM_001366230.1; = p.I376S on NM_001010000.3) | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV51634456; called by muse, mutect2
- ARHGAP29 | c.2939A>G p.E980G | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV53110009; called by muse, mutect2, varscan2
- ARHGAP29 | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as rs748894382, COSV53110021; called by muse, mutect2, varscan2
- ARHGAP30 | c.883T>G p.L295V | Missense Mutation (SNP) | VAF 22/397 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); catalogued as COSV63515478; called by muse, mutect2
- ARHGAP30 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757669760, COSV63515484; called by muse, mutect2, varscan2
- ARHGAP31 | c.340A>G p.K114E | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV51790821; called by muse, mutect2, varscan2
- ARHGAP32 | c.2294G>A p.G765E (on ENST00000310343 / NM_001378025.1; = p.G416E on NM_014715.4) | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV59845214; called by muse, mutect2, varscan2
- ARHGAP32 | c.605A>G p.D202G | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV59845228; called by muse, mutect2, varscan2
- ARHGDIB | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1455599046, COSV57455600; called by muse, mutect2, varscan2
- ARHGEF10 | c.3646G>A p.V1216I (on ENST00000398564; = p.V1191I on NM_014629.4) | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.317); catalogued as rs577376669, COSV50644719; called by muse, mutect2, varscan2
- ARHGEF12 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs767889107, COSV63102781; called by muse, mutect2, varscan2
- ARHGEF12 | c.4095G>A p.M1365I | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); catalogued as COSV63103443; called by muse, mutect2, varscan2
- ARHGEF19 | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as rs1409636655, COSV54615932; called by muse, mutect2
- ARHGEF25 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV54085419; called by muse, mutect2, varscan2
- ARHGEF25 | c.1598A>G p.E533G | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV54085428; called by muse, mutect2, varscan2
- ARHGEF28 | c.1955G>A p.R652Q | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.905); catalogued as rs375756705, COSV55251604; called by muse, mutect2, varscan2
- ARHGEF28 | c.4749T>G p.N1583K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV55251626; called by muse, mutect2, varscan2
- ARHGEF4 | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.224); catalogued as rs767784717, COSV58119639; called by muse, mutect2, varscan2
- ARHGEF40 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs763446664, COSV53879066; called by muse, mutect2, varscan2
- ARHGEF6 | c.2047G>T p.D683Y | Missense Mutation (SNP) | VAF 110/138 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV51688847; called by muse, mutect2, varscan2
- ARID1A | c.3010A>G p.T1004A | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as rs1254141515, COSV61374326; called by muse, mutect2, varscan2
- ARID1A | c.3377C>T p.S1126F | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV61374333; called by muse, mutect2, varscan2
- ARID4A | c.3049C>T p.R1017* | Nonsense Mutation (SNP) | VAF 64/192 reads (33%) | catalogued as rs1344759651, COSV62162823; called by muse, mutect2, varscan2
- ARID4B | c.1758A>C p.K586N | Missense Mutation (SNP) | VAF 137/246 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1199079888, COSV51600803; called by muse, mutect2, varscan2
- ARID4B | c.1273G>T p.E425* | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | catalogued as COSV51600823; called by muse, mutect2, varscan2
- ARIH2 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 70/208 reads (34%) | catalogued as COSV62704240; called by muse, mutect2, varscan2
- ARMC1 | c.8C>A p.S3Y | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV52533344; called by muse, mutect2, varscan2
- ARMC2 | c.2305G>T p.D769Y | Missense Mutation (SNP) | VAF 83/241 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV64550529, COSV64553671; called by muse, mutect2, varscan2
- ARMC4 | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV53463852; called by muse, mutect2, varscan2
- ARNT | c.2329G>T p.E777* | Nonsense Mutation (SNP) | VAF 20/125 reads (16%) | catalogued as COSV55011206; called by muse, mutect2, varscan2
- ARNTL | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62985867; called by muse, mutect2, varscan2
- ARNTL2 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140062821; called by muse, mutect2, varscan2
- ARPP21 | c.687A>G p.I229M | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV51794542; called by muse, varscan2
- ARPP21 | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 20/78 reads (26%) | catalogued as COSV51794552, COSV51810314; called by muse, varscan2
- ARRDC3 | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 38/122 reads (31%) | catalogued as COSV54364804, COSV54365403; called by muse, mutect2, varscan2
- ARRDC3 | c.248A>G p.N83S | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV54364812; called by muse, mutect2
- ART4 | c.125G>A p.R42K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.97); PolyPhen benign (0.03); catalogued as COSV57451472; called by muse, mutect2, varscan2
- ASAP1 | c.2840C>T p.A947V | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.024); catalogued as rs926280708, COSV63046266; called by muse, mutect2, varscan2
- ASB11 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1251367099, COSV60354720; called by muse, mutect2, varscan2
- ASB15 | c.1624C>T p.R542W | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749450721, COSV51924783, COSV51925013; called by muse, mutect2, varscan2
- ASB18 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); catalogued as rs376276467, COSV68960162; called by muse, mutect2, varscan2
- ASB5 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs751252627, COSV56668485; called by muse, mutect2, varscan2
- ASB9 | c.578T>C p.V193A | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.26); catalogued as COSV66851463; called by muse, mutect2, varscan2
- ASCC3 | c.3694A>G p.I1232V | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV61227207; called by muse, mutect2, varscan2
- ASCC3 | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs142555952, COSV61227213; called by muse, mutect2, varscan2
- ASCC3 | c.935A>C p.K312T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV61227225; called by muse, mutect2
- ASF1A | c.165A>C p.Q55H | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV57647552; called by muse, mutect2, varscan2
- ASF1A | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 86/140 reads (61%) | catalogued as COSV57647566, COSV57648220; called by muse, mutect2, varscan2
- ASH1L | c.7538C>T p.A2513V (on ENST00000368346 / NM_001366177.2; = p.A2508V on NM_018489.3) | Missense Mutation (SNP) | VAF 66/129 reads (51%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.054); catalogued as COSV64206625; called by muse, mutect2, varscan2
- ASH1L | c.3889C>T p.R1297C | Missense Mutation (SNP) | VAF 137/251 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV64206629; called by muse, mutect2, varscan2
- ASMT | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as rs763023784, COSV67109708; called by muse, mutect2, varscan2
- ASNS | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.328); catalogued as COSV51551220; called by muse, mutect2, varscan2
- ASPG | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs771570066, COSV71933691; called by muse, mutect2, varscan2
- ASPH | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.209); catalogued as rs758840739, COSV62858475; called by muse, mutect2, varscan2
- ASPM | c.8579A>C p.K2860T | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.81); catalogued as COSV54127309; called by muse, mutect2, varscan2
- ASPM | c.1095T>G p.I365M | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs375572921; called by muse, mutect2, varscan2
- ASTE1 | c.705C>A p.F235L | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as COSV53908184; called by muse, mutect2, varscan2
- ASTN1 | c.3010C>T p.R1004* | Nonsense Mutation (SNP) | VAF 52/96 reads (54%) | catalogued as rs1357604735, COSV62493153; called by muse, mutect2, varscan2
- ASTN1 | c.1498C>T p.R500W | Missense Mutation (SNP) | VAF 352/627 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752367629, COSV56060646; called by muse, mutect2, varscan2
- ASTN2 | c.4006T>C p.S1336P (on ENST00000313400 / NM_001365069.1; = p.S1285P on NM_014010.5) | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.477); catalogued as COSV56001568; called by muse, mutect2, varscan2
- ASTN2 | c.1957C>T p.R653C (on ENST00000313400 / NM_001365069.1; = p.R602C on NM_014010.5) | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759200691, COSV57763735, COSV57810099; called by muse, mutect2, varscan2
- ASXL2 | c.3223C>T p.R1075W | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs200946888; called by muse, mutect2, varscan2
- ASXL3 | c.3704C>A p.S1235Y | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.115); catalogued as rs1468967860, COSV52461645, COSV52474635; called by muse, mutect2, varscan2
- ASZ1 | c.145A>C p.K49Q | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as COSV52912124; called by muse, mutect2, varscan2
- ATF7IP | c.935A>C p.K312T | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); catalogued as COSV53768218; called by muse, mutect2, varscan2
- ATG13 | c.56T>G p.F19C | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56318348; called by muse, mutect2, varscan2
- ATG4C | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 30/74 reads (41%) | catalogued as COSV58603846; called by muse, mutect2, varscan2
- ATG4C | c.281A>C p.E94A | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV58604838; called by muse, mutect2, varscan2
- ATG9A | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.968); catalogued as rs1441391562, COSV54694341; called by muse, mutect2, varscan2
- ATL1 | c.1665G>T p.K555N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.023); catalogued as COSV61204556; called by muse, mutect2
- ATM | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.207); catalogued as COSV53734646; called by muse, mutect2, varscan2
- ATM | c.8435C>A p.S2812Y | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.735); catalogued as CD162053, COSV53734098; called by muse, varscan2
- ATOH8 | c.123A>C p.K41N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV60399940; called by muse, mutect2, varscan2
- ATP10A | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as rs138618267; called by muse, mutect2, varscan2
- ATP10B | c.4197C>G p.H1399Q | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.001); catalogued as rs763853398, COSV59147206; called by muse, mutect2, varscan2
- ATP10B | c.4004A>G p.D1335G | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as rs768897810, COSV59147216; called by muse, mutect2, varscan2
- ATP11A | c.3142C>A p.L1048I | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as COSV52108617; called by muse, mutect2, varscan2
- ATP11B | c.3493A>G p.S1165G | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV60027281; called by muse, mutect2, varscan2
- ATP12A | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV54514217, COSV54521366; called by muse, mutect2, varscan2
- ATP13A3 | c.3316T>G p.F1106V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.7); PolyPhen benign (0.014); catalogued as COSV55462706; called by muse, mutect2, varscan2
- ATP13A3 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as rs755718276, COSV55462722; called by muse, mutect2, varscan2
- ATP13A4 | c.1441A>C p.N481H | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55067614; called by muse, mutect2, varscan2
- ATP13A4 | c.77G>T p.R26L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV55067634; called by muse, mutect2, varscan2
- ATP1A1 | c.2203G>A p.G735R | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55190478; called by muse, mutect2, varscan2
- ATP1A2 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 93/148 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63403014; called by muse, mutect2, varscan2
- ATP1B1 | c.226+1G>A p.X76_splice | Splice Site (SNP) | VAF 21/101 reads (21%) | catalogued as COSV63179073, COSV63179367; called by muse, mutect2, varscan2
- ATP1B2 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 94/290 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.719); catalogued as rs779294665, COSV51515257; called by muse, mutect2
- ATP2A2 | c.2185G>A p.A729T | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs886048953, COSV57875184; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2B1 | c.2287C>T p.R763* | Nonsense Mutation (SNP) | VAF 73/211 reads (35%) | catalogued as COSV53805728; called by muse, mutect2, varscan2
- ATP2B3 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 79/141 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs782427304, COSV54843062; called by muse, mutect2, varscan2
- ATP5F1C | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as rs1436478284, COSV59620786; called by muse, mutect2, varscan2
- ATP5F1C | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV59621269; called by muse, mutect2, varscan2
- ATP5PF | c.290-1G>A p.X97_splice | Splice Site (SNP) | VAF 23/74 reads (31%) | catalogued as COSV99535446; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2000G>A p.R667Q | Missense Mutation (SNP) | VAF 90/250 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs759959455, COSV59473910; called by muse, mutect2, varscan2
- ATP6V1A | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs746407800, COSV56361497; called by muse, mutect2, varscan2
- ATP6V1B1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.024); catalogued as rs143516810; called by muse, mutect2, varscan2
- ATP8A1 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.031); catalogued as COSV52531473; called by muse, mutect2
- ATP8A2 | c.2452G>A p.A818T | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs768582040, COSV54944305; called by muse, mutect2, varscan2
- ATP8B1 | c.2089G>T p.D697Y | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs762857853, COSV52173943; called by muse, mutect2, varscan2
- ATP8B2 | c.1631G>A p.R544H (on ENST00000672630; = p.R511H on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.987); catalogued as rs758569511, COSV59245397; called by muse, mutect2, varscan2
- ATP8B3 | c.1330T>C p.S444P | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV59541386; called by muse, mutect2, varscan2
- ATR | c.6607C>A p.H2203N | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV63385250; called by muse, mutect2, varscan2
- ATR | c.4678G>A p.D1560N | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs756354361, COSV63385253, COSV63387928; called by muse, mutect2, varscan2
- ATR | c.293-1G>T p.X98_splice | Splice Site (SNP) | VAF 40/122 reads (33%) | catalogued as COSV63385256; called by muse, mutect2, varscan2
- ATRNL1 | c.1744T>G p.F582V | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV61800509; called by muse, mutect2, varscan2
- ATRX | c.2347A>C p.S783R | Missense Mutation (SNP) | VAF 109/167 reads (65%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.109); catalogued as COSV64873728; called by muse, mutect2, varscan2
- ATXN3 | c.1067C>A p.S356Y (on ENST00000545170; = p.S347Y on NM_004993.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV61494284; called by muse, mutect2, varscan2
- AUTS2 | c.2326G>A p.G776S | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.369); catalogued as rs747429714, COSV100717819, COSV61389797; called by muse, mutect2, varscan2
- AVPR2 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 218/271 reads (80%) | SIFT tolerated (0.45); PolyPhen benign (0.025); catalogued as rs138974323, COSV61685966; called by muse, mutect2, varscan2
- AXDND1 | c.1388T>C p.V463A | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs761760918, COSV62640967; called by muse, mutect2, varscan2
- AXDND1 | c.3020C>T p.S1007F | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV62640971; called by muse, mutect2, varscan2
- B3GALT2 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 97/183 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as rs767764174, COSV66463911; called by muse, mutect2, varscan2
- B3GNT5 | c.830C>A p.S277* | Nonsense Mutation (SNP) | VAF 29/96 reads (30%) | catalogued as COSV58475667; called by muse, mutect2, varscan2
- B4GALNT2 | c.1189C>A p.L397I | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100302671, COSV55925397; called by muse, mutect2, varscan2
- B4GALNT3 | c.2267A>G p.D756G | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56751157; called by muse, mutect2, varscan2
- B4GALNT4 | c.2660G>A p.R887Q | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.098); catalogued as rs761242637, COSV57322330; called by muse, mutect2, varscan2
- BACE2 | c.908A>G p.D303G | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57738399; called by muse, mutect2, varscan2
- BAG3 | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 85/200 reads (43%) | catalogued as COSV64841819; called by muse, mutect2, varscan2
- BAP1 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.618); catalogued as rs1268089896, COSV56232361; called by muse, mutect2, varscan2
- BARHL2 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs773469826, COSV64981009; called by muse, mutect2, varscan2
- BAZ1A | c.4508C>T p.S1503L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1389574742, COSV62409622; called by muse, mutect2, varscan2
- BAZ1B | c.3621A>C p.K1207N | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV59989840; called by muse, mutect2, varscan2
- BAZ2A | c.2204G>T p.R735I | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV51633854; called by muse, mutect2, varscan2
- BAZ2B | c.5664T>G p.I1888M | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV58597754; called by muse, mutect2, varscan2
- BAZ2B | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.772); catalogued as COSV58597763; called by muse, mutect2, varscan2
- BAZ2B | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.114); catalogued as rs753545631, COSV58597770; called by muse, mutect2, varscan2
- BBS2 | c.1352T>C p.V451A | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV55325660; called by muse, mutect2, varscan2
- BBS4 | c.26G>T p.R9I | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV51437174; called by muse, mutect2, varscan2
- BBS9 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 67/201 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV54161478; called by muse, mutect2, varscan2
- BCAN | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV61256048; called by muse, mutect2, varscan2
- BCAN | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61256058; called by muse, mutect2, varscan2
- BCAR3 | c.328C>A p.L110I | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV53073645; called by muse, mutect2, varscan2
- BCL9 | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 51/250 reads (20%) | catalogued as COSV52341987; called by muse, mutect2, varscan2
- BCL9L | c.2464G>A p.A822T | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV52683024; called by muse, mutect2, varscan2
- BCLAF1 | c.2353G>T p.E785* | Nonsense Mutation (SNP) | VAF 46/156 reads (29%) | catalogued as COSV50357247, COSV99219755; called by muse, mutect2, varscan2
- BCLAF1 | c.2201A>C p.K734T | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV50357252; called by muse, mutect2, varscan2
- BCLAF1 | c.1186G>T p.D396Y | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV62144244; called by muse, mutect2, varscan2
- BCO2 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs764094222, COSV63062697, COSV63064809; called by muse, mutect2, varscan2
- BDNF | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 48/164 reads (29%) | catalogued as rs772989712, COSV59234017; called by muse, mutect2, varscan2
- BDP1 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.04); catalogued as rs142464289, COSV62430286; called by muse, mutect2, varscan2
- BDP1 | c.2917G>A p.V973M | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs1294144594, COSV62430297; called by muse, mutect2, varscan2
- BDP1 | c.4630G>A p.D1544N | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV62430302; called by muse, mutect2, varscan2
- BDP1 | c.5239G>T p.D1747Y | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62430306; called by muse, mutect2, varscan2
- BDP1 | c.7658A>G p.E2553G | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV62429732; called by muse, mutect2
- BEND7 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV61988001; called by muse, mutect2, varscan2
- BFSP2 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as rs751496741, COSV56587692, COSV56589120; called by muse, mutect2, varscan2
- BHLHE41 | c.289A>C p.K97Q | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV54378433; called by muse, mutect2, varscan2
- BICC1 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1035741792, COSV65857705; called by muse, mutect2, varscan2
- BIRC6 | c.2264A>C p.E755A | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.358); catalogued as COSV70197242; called by muse, mutect2, varscan2
- BIRC6 | c.8140A>C p.T2714P | Missense Mutation (SNP) | VAF 72/207 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.305); catalogued as COSV70197247; called by muse, mutect2, varscan2
- BIRC6 | c.11698G>T p.E3900* | Nonsense Mutation (SNP) | VAF 3/10 reads (30%) | catalogued as COSV70197254; called by muse, mutect2
- BIRC6 | c.12013A>C p.T4005P | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV66042812; called by muse, mutect2, varscan2
- BIRC6 | c.12533G>T p.R4178I | Missense Mutation (SNP) | VAF 73/172 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV70197262; called by muse, mutect2, varscan2
- BIRC6 | c.13541A>C p.K4514T | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.053); catalogued as COSV70197267; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.198T>G p.I66M | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.788); catalogued as COSV57278829; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1706A>G p.K569R | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV63244495; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2111T>C p.V704A | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.952); catalogued as COSV63244503; called by muse, mutect2
- BIVM-ERCC5 | c.4114T>A p.L1372I | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63244509; called by muse, varscan2
- BLVRA | c.676A>C p.N226H | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.749); catalogued as COSV55513315; called by muse, mutect2, varscan2
- BMP10 | c.1262G>A p.C421Y | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54894598; called by muse, varscan2
- BMP3 | c.749C>A p.S250Y | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV51082185, COSV51082245, COSV51088256; called by muse, mutect2, varscan2
- BMP3 | c.1347C>A p.F449L | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51082268; called by muse, mutect2, varscan2
- BMP5 | c.785A>C p.N262T | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.431); catalogued as COSV63701997; called by muse, mutect2, varscan2
- BMP7 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs919226290, COSV67780010; called by muse, mutect2, varscan2
- BMP7 | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV67780098; called by muse, mutect2, varscan2
- BNC1 | c.2903C>T p.S968L | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs968421847, COSV61756810; called by muse, mutect2, varscan2
- BNIP3 | c.684A>C p.K228N | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV64043754; called by muse, mutect2, varscan2
- BNIP5 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.736); catalogued as rs141030977; called by muse, mutect2, varscan2
- BOC | c.2212G>A p.A738T | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as COSV56348848; called by muse, mutect2, varscan2
- BOC | c.3283A>G p.M1095V | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV56348861; called by muse, mutect2, varscan2
- BOD1L1 | c.8855A>C p.K2952T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV50008566, COSV50014909; called by muse, mutect2, varscan2
- BPGM | c.507G>T p.W169C | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61324298; called by muse, mutect2, varscan2
- BPIFA2 | c.4C>A p.L2I | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.222); catalogued as COSV53610622; called by muse, mutect2, varscan2
- BPIFA2 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as rs200885048, COSV53610632; called by muse, mutect2, varscan2
- BPIFB1 | c.593A>G p.N198S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53605757; called by muse, mutect2, varscan2
- BPTF | c.4952G>T p.S1651I | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.133); catalogued as COSV58834268; called by muse, mutect2, varscan2
- BRCA1 | c.2679G>T p.K893N | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs587781771, COSV58786902; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.1403G>T p.R468I | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.554); catalogued as COSV66450890; called by muse, mutect2, varscan2
- BRCA2 | c.7355A>C p.N2452T | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as COSV66450907, COSV66455492; called by muse, mutect2, varscan2
- BRD3 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57702323; called by muse, mutect2, varscan2
- BRD7 | c.447-1G>T p.X149_splice | Splice Site (SNP) | VAF 24/60 reads (40%) | catalogued as COSV67158488; called by muse, mutect2, varscan2
- BRDT | c.858G>T p.K286N | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62864021, COSV62864626; called by muse, mutect2, varscan2
- BRICD5 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs374423982; called by muse, mutect2, varscan2
- BRINP3 | c.1994A>G p.N665S | Missense Mutation (SNP) | VAF 95/196 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1051758519, COSV66517926; called by muse, mutect2, varscan2
- BRINP3 | c.236G>A p.R79K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100819127, COSV66517935; called by muse, mutect2, varscan2
- BRIP1 | c.2692G>A p.D898N | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV51996593; called by muse, mutect2, varscan2
- BROX | c.1214A>G p.D405G | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.7); catalogued as COSV61799071; called by muse, mutect2, varscan2
- BRSK1 | c.588T>G p.Y196* | Nonsense Mutation (SNP) | VAF 30/90 reads (33%) | catalogued as COSV58665508; called by muse, mutect2, varscan2
- BSN | c.3687T>G p.Y1229* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV56515091; called by muse, mutect2, varscan2
- BSN | c.6137G>A p.R2046H | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748620628, COSV56514874, COSV56515103; called by muse, mutect2, varscan2
- BTBD1 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 153/484 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779159787, COSV55602314, COSV99915799; called by muse, mutect2, varscan2
- BTBD16 | c.198C>A p.F66L | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs1285561710, COSV53261777; called by muse, mutect2, varscan2
- BTD | c.1030A>T p.I344F | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.034); catalogued as COSV57728747; called by muse, mutect2, varscan2
- BTN3A2 | c.923T>C p.L308P | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV62686951; called by muse, mutect2, varscan2
- BUB1 | c.108G>T p.E36D | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.798); catalogued as rs1801328; called by muse, mutect2, varscan2
- BUB1B | c.338A>C p.K113T | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV55010893; called by muse, mutect2, varscan2
- BUB1B | c.2437G>T p.E813* | Nonsense Mutation (SNP) | VAF 27/72 reads (38%) | catalogued as COSV55010918; called by muse, mutect2, varscan2
- BUD31 | c.272A>C p.K91T | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52862272; called by muse, mutect2, varscan2
- BVES | c.331C>A p.L111I | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.804); catalogued as rs760966564, COSV58947103; called by muse, mutect2, varscan2
- BYSL | c.620T>C p.I207T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV57828162; called by muse, mutect2, varscan2
- C10orf67 | c.373C>A p.L125I (on ENST00000323327; = p.L126I on NM_153714.3) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV60113120; called by muse, mutect2, varscan2
- C10orf88 | c.1144C>A p.L382I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.217); catalogued as rs570222008, COSV64403824; called by muse, mutect2, varscan2
- C12orf50 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV53894213; called by muse, mutect2, varscan2
- C12orf57 | c.71T>C p.I24T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.451); catalogued as COSV57546587; called by muse, mutect2, varscan2
- C12orf60 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV57451460; called by muse, mutect2, varscan2
- C14orf39 | c.1489A>G p.I497V | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV58780475; called by muse, mutect2, varscan2
- C14orf39 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs760333498, COSV58780487; called by muse, mutect2, varscan2
- C16orf46 | c.37A>C p.N13H | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV55150675; called by muse, mutect2, varscan2
- C16orf54 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.74); catalogued as rs1316976170, COSV61476691; called by muse, mutect2, varscan2
- C16orf89 | c.825T>G p.I275M | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60122941; called by muse, mutect2, varscan2
- C17orf75 | c.785C>A p.T262N | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.943); catalogued as COSV56752501; called by muse, mutect2, varscan2
- C1GALT1 | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV56179026; called by muse, mutect2, varscan2
- C1GALT1 | c.796T>A p.F266I | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56179045; called by muse, mutect2, varscan2
- C1GALT1C1 | c.923T>C p.V308A | Missense Mutation (SNP) | VAF 111/136 reads (82%) | SIFT tolerated (0.23); PolyPhen benign (0.045); catalogued as COSV58973913; called by muse, mutect2, varscan2
- C1GALT1C1L | c.449A>C p.E150A | Missense Mutation (SNP) | VAF 112/317 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV56751267; called by muse, mutect2, varscan2
- C1QTNF2 | c.311G>A p.R104Q (on ENST00000393975; = p.R59Q on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs759937511, COSV67432358; called by muse, mutect2, varscan2
- C1QTNF3 | c.84+6C>T | Splice Region (SNP) | VAF 68/223 reads (30%) | catalogued as rs544070128, COSV99180699; called by muse, mutect2, varscan2
- C1orf112 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs754547047, COSV53677535; called by muse, mutect2, varscan2
- C1orf141 | c.957G>T p.Q319H | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV63992007; called by muse, mutect2, varscan2
- C1orf141 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as rs1214656440, COSV63992367; called by muse, mutect2
- C20orf194 | c.2048C>T p.A683V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV52693629; called by muse, mutect2, varscan2
- C20orf194 | c.668C>A p.S223Y | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV52693681; called by muse, mutect2, varscan2
- C2CD3 | c.2190T>A p.N730K | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV58091450; called by muse, mutect2, varscan2
- C2CD5 | c.2377G>A p.A793T | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.487); catalogued as rs750393334, COSV61723353; called by muse, mutect2, varscan2
- C2CD5 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61722731; called by muse, mutect2, varscan2
- C2orf16 | c.2848A>G p.I950V | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.051); catalogued as COSV62674541; called by muse, mutect2, varscan2
- C2orf16 | c.4427G>A p.R1476K | Missense Mutation (SNP) | VAF 61/187 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV62674547; called by muse, mutect2, varscan2
- C2orf69 | c.352A>G p.T118A | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.96); PolyPhen benign (0.007); catalogued as COSV60666124; called by muse, mutect2, varscan2
- C2orf78 | c.2585T>C p.V862A | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV68516912; called by muse, mutect2, varscan2
- C3 | c.2035C>T p.R679* | Nonsense Mutation (SNP) | VAF 42/121 reads (35%) | catalogued as COSV55570751; called by muse, mutect2, varscan2
- C3 | c.1348G>T p.G450C | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV55570760; called by muse, mutect2, varscan2
- C3 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55570775; called by muse, mutect2, varscan2
- C4BPB | c.660G>T p.E220D | Missense Mutation (SNP) | VAF 79/141 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as COSV54691089; called by muse, mutect2, varscan2
- C4orf50 | c.779G>T p.S260I (on ENST00000324058; = p.S1492I on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60687991; called by muse, mutect2, varscan2
- C5 | c.3616C>T p.R1206C | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1402957355, COSV56324454; called by muse, mutect2, varscan2
- C5orf24 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57542671; called by muse, mutect2, varscan2
- C5orf34 | c.1652C>T p.S551L | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs746690868, COSV60928857; called by muse, mutect2, varscan2
- C6 | c.866G>A p.R289K | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54707573; called by muse, mutect2, varscan2
- C6orf118 | c.785A>C p.Q262P | Missense Mutation (SNP) | VAF 78/151 reads (52%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV57813737; called by muse, mutect2, varscan2
- C8orf34 | c.1328A>G p.D443G | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV57400012; called by muse, mutect2, varscan2
- C8orf44-SGK3 | c.-481G>A | Splice Region (SNP) | VAF 23/63 reads (37%) | catalogued as COSV66402180; called by muse, mutect2, varscan2
- C9 | c.180A>C p.Q60H | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.176); catalogued as COSV54675401; called by muse, mutect2, varscan2
- C9orf131 | c.2036A>G p.N679S | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.561); catalogued as COSV56610153; called by muse, mutect2, varscan2
- C9orf64 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs898282719, COSV59032333; called by muse, varscan2
- CA8 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 18/71 reads (25%) | catalogued as rs749446493, COSV58771282; called by muse, mutect2, varscan2
- CAB39L | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV61714239; called by muse, mutect2, varscan2
- CABIN1 | c.2624C>T p.A875V | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs201926665, COSV54079714; called by muse, mutect2, varscan2
- CABS1 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs540614090, COSV56733253; called by muse, mutect2, varscan2
- CACHD1 | c.202A>G p.I68V | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as rs762107626, COSV51550961; called by muse, mutect2, varscan2
- CACNA1A | c.4079T>C p.I1360T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV64193547; called by muse, mutect2, varscan2
- CACNA1A | c.2549A>G p.D850G | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as COSV64193571; called by muse, mutect2, varscan2
- CACNA1B | c.4597G>A p.D1533N | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV53119920; called by muse, mutect2, varscan2
- CACNA1B | c.6814G>A p.A2272T | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs763026357, COSV53119943; called by muse, mutect2, varscan2
- CACNA1D | c.1432A>C p.N478H | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as COSV55441778; called by muse, mutect2, varscan2
- CACNA1D | c.6259G>A p.E2087K (on ENST00000350061 / NM_001128840.3; = p.E2107K on NM_000720.4) | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as rs762059527, COSV55436089, COSV55439012; called by muse, mutect2, varscan2
- CACNA1E | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.63); catalogued as rs1305652887, COSV62386898; called by muse, mutect2, varscan2
- CACNA1F | c.1794C>A p.C598* | Nonsense Mutation (SNP) | VAF 11/17 reads (65%) | catalogued as CM158286, COSV59903681; called by muse, mutect2, varscan2
- CACNA1H | c.6086A>G p.D2029G | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.058); catalogued as COSV52353384; called by muse, mutect2
- CACNA1I | c.2414A>G p.D805G | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60803915; called by muse, mutect2, varscan2
- CACNA1S | c.4310A>C p.K1437T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62938067; called by muse, mutect2, varscan2
- CACNG5 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs142426129, COSV50054657; called by muse, mutect2, varscan2
- CACNG7 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1369066152, COSV55813728; called by muse, mutect2, varscan2
- CAD | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs761642796, COSV53024976; called by muse, mutect2, varscan2
- CADM1 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.479); catalogued as rs1158887836, COSV59006265; called by muse, mutect2, varscan2
- CADM3 | c.274G>A p.E92K (on ENST00000368125 / NM_001127173.3; = p.E126K on NM_021189.5) | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs888060211, COSV63683587; called by muse, mutect2, varscan2
- CADPS | c.2035G>A p.A679T | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.041); catalogued as rs376619081, COSV51878134; called by muse, mutect2, varscan2
- CADPS | c.1104G>T p.Q368H | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as COSV51872807; called by muse, mutect2, varscan2
- CAGE1 | c.1478A>C p.K493T (on ENST00000512086; = p.K357T on NM_205864.3) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV57075816; called by muse, mutect2, varscan2
- CALB1 | c.712A>G p.I238V | Missense Mutation (SNP) | VAF 79/209 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.707); catalogued as rs1434592291, COSV55367007; called by muse, mutect2, varscan2
- CALB2 | c.230A>C p.K77T | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.217); catalogued as COSV56938668; called by muse, mutect2, varscan2
- CALB2 | c.793C>T p.L265F | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs767492769, COSV56938313, COSV56938675; called by muse, mutect2, varscan2
- CALD1 | c.11T>G p.F4C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62646339; called by muse, mutect2, varscan2
- CALD1 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62646346; called by muse, mutect2, varscan2
- CAMK2A | c.1120G>A p.D374N (on ENST00000348628 / NM_171825.2; = p.D385N on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.183); catalogued as COSV62245757, COSV62246315; called by muse, mutect2, varscan2
- CAMKMT | c.927A>C p.E309D | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV65924316; called by muse, mutect2, varscan2
- CAMLG | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765331970, COSV51804427; called by muse, mutect2, varscan2
- CAMP | c.401G>T p.R134I (on ENST00000296435; = p.R131I on NM_004345.5) | Missense Mutation (SNP) | VAF 77/234 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.074); catalogued as rs1428353784, COSV56481848, COSV99601296; called by muse, mutect2, varscan2
- CAMSAP1 | c.4491G>T p.K1497N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56720602; called by muse, mutect2, varscan2
- CAMTA1 | c.4567G>T p.E1523* | Nonsense Mutation (SNP) | VAF 30/98 reads (31%) | catalogued as COSV57890360; called by muse, mutect2, varscan2
- CAND2 | c.2030A>G p.D677G (on ENST00000456430 / NM_001162499.2; = p.D584G on NM_012298.3) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV55988358; called by muse, varscan2
- CAPN3 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs1273129397, COSV58820640; called by mutect2, varscan2
- CAPRIN1 | c.606-2A>C p.X202_splice | Splice Site (SNP) | VAF 44/128 reads (34%) | catalogued as COSV58219009; called by muse, mutect2, varscan2
- CAPRIN2 | c.2180G>A p.R727Q | Missense Mutation (SNP) | VAF 69/219 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.361); catalogued as rs756534335, COSV51831573, COSV99195654; called by muse, mutect2, varscan2
- CARD11 | c.1429T>G p.S477A | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV62754670; called by muse, mutect2, varscan2
- CARD14 | c.710A>G p.N237S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV60122567; called by muse, mutect2, varscan2
- CARD18 | c.35T>G p.I12S | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.407); catalogued as COSV73233161; called by muse, mutect2, varscan2
- CARD6 | c.1276G>T p.D426Y | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54565082; called by muse, mutect2, varscan2
- CARMIL2 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs747119629, COSV58024474; called by muse, mutect2, varscan2
- CARNS1 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs1007612294, COSV57130071; called by muse, mutect2, varscan2
- CARS1 | c.1387T>C p.F463L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.829); catalogued as COSV53451940; called by muse, mutect2, varscan2
- CARS2 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 85/234 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs753936012, COSV57284437; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASKIN1 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.94); PolyPhen benign (0.2); catalogued as rs747089821, COSV58871029; called by muse, mutect2, varscan2
- CASP4 | c.1035G>A p.K345= | Splice Region (SNP) | VAF 33/144 reads (23%) | catalogued as COSV67744278; called by muse, mutect2, varscan2
- CASP5 | c.*2A>C | Splice Region (SNP) | VAF 25/63 reads (40%) | catalogued as COSV99507447; called by muse, mutect2, varscan2
- CASP8AP2 | c.5372A>T p.E1791V | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV52745987; called by muse, mutect2, varscan2
- CASQ1 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs754341004, COSV63623999; called by muse, mutect2, varscan2
- CASS4 | c.1595A>G p.E532G | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.096); catalogued as COSV64385731; called by muse, mutect2, varscan2
- CAST | c.175G>T p.E59* (on ENST00000341926; = p.E142* on NM_001750.7 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 26/72 reads (36%) | catalogued as COSV57784157; called by muse, mutect2, varscan2
- CATSPERB | c.1958A>C p.D653A | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56424090; called by muse, mutect2, varscan2
- CATSPERB | c.1081C>T p.L361F | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs545114453, COSV56424106, COSV56432713; called by muse, mutect2, varscan2
- CBFA2T3 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as rs376580768; called by muse, mutect2, varscan2
- CBFA2T3 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs779831852, COSV51925059; called by muse, mutect2, varscan2
- CBLIF | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 75/170 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.279); catalogued as rs771992791, COSV57238359; called by muse, mutect2, varscan2
- CBWD2 | c.432T>C p.G144= | Splice Region (SNP) | VAF 37/156 reads (24%) | catalogued as COSV99380438; called by muse, mutect2, varscan2
- CBWD2 | c.642G>T p.K214N | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52073508; called by muse, mutect2, varscan2
- CC2D1B | c.1831C>T p.R611* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as rs551443049, COSV52559179; called by muse, mutect2, varscan2
- CC2D2A | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.025); catalogued as rs778519147, COSV67502850; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CC2D2A | c.4070T>G p.F1357C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV67502865; called by muse, mutect2, varscan2
- CCAR1 | c.2260G>A p.D754N | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV56268463, COSV99771233; called by muse, mutect2, varscan2
- CCDC105 | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 33/114 reads (29%) | catalogued as COSV52963562; called by muse, mutect2, varscan2
- CCDC110 | c.1470T>G p.I490M | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.509); catalogued as COSV56870052; called by muse, mutect2
- CCDC110 | c.741A>C p.Q247H | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV56870061; called by muse, mutect2, varscan2
- CCDC116 | c.845A>C p.Q282P | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53037358; called by muse, mutect2, varscan2
- CCDC117 | c.304C>A p.L102I | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV50770667; called by muse, mutect2, varscan2
- CCDC122 | c.808G>T p.G270* | Nonsense Mutation (SNP) | VAF 22/78 reads (28%) | catalogued as COSV71573667; called by muse, mutect2, varscan2
- CCDC138 | c.1730C>A p.S577Y | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV54565802; called by muse, mutect2, varscan2
- CCDC141 | c.4295T>C p.V1432A | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55371154; called by muse, mutect2, varscan2
- CCDC146 | c.2387A>C p.K796T | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV53545925; called by muse, mutect2, varscan2
- CCDC146 | c.2621G>A p.R874Q | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs779767745, COSV53545939; called by muse, mutect2, varscan2
- CCDC15 | c.2619G>T p.E873D | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV61080862; called by muse, mutect2, varscan2
- CCDC158 | c.2873G>A p.S958N | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.215); catalogued as COSV66355471; called by muse, mutect2, varscan2
- CCDC160 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 30/33 reads (91%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as rs1448544224, COSV66251345; called by muse, mutect2, varscan2
- CCDC170 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.386); catalogued as rs761025789, COSV53338971; called by muse, mutect2, varscan2
- CCDC170 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.067); catalogued as COSV53338978, COSV53346884; called by muse, mutect2, varscan2
- CCDC171 | c.48G>T p.K16N | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.961); catalogued as rs542355675, COSV52637947; called by muse, mutect2, varscan2
- CCDC171 | c.1117G>T p.E373* | Nonsense Mutation (SNP) | VAF 23/62 reads (37%) | catalogued as COSV52637961; called by muse, mutect2, varscan2
- CCDC171 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as rs1476713051, COSV52637975; called by muse, mutect2, varscan2
- CCDC171 | c.3549G>T p.E1183D | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV52637988; called by muse, mutect2, varscan2
- CCDC178 | c.2444T>C p.V815A (on ENST00000383096 / NM_001105528.3; = p.V777A on NM_198995.3) | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as COSV55766165, COSV55799838; called by muse, mutect2, varscan2
- CCDC18 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as COSV58142114; called by muse, mutect2, varscan2
- CCDC18 | c.3181G>T p.E1061* (on ENST00000343253 / NM_001306076.1; = p.E1062* on NM_206886.4) | Nonsense Mutation (SNP) | VAF 20/62 reads (32%) | catalogued as COSV58142120; called by muse, mutect2, varscan2
- CCDC185 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as rs1359680074, COSV64820536; called by muse, mutect2, varscan2
- CCDC186 | c.2332A>C p.K778Q | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV65160875; called by muse, mutect2, varscan2
- CCDC30 | c.484G>T p.D162Y (on ENST00000340612; = p.D119Y on NM_001080850.3) | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV100501291, COSV59605274; called by muse, mutect2, varscan2
- CCDC38 | c.104T>G p.L35R | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100717518; called by muse, mutect2, varscan2
- CCDC38 | c.103C>A p.L35I | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as COSV100717520; called by muse, mutect2, varscan2
- CCDC39 | c.1277C>T p.T426I | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.857); catalogued as COSV56480915; called by muse, mutect2, varscan2
- CCDC42 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs142451736; called by muse, mutect2, varscan2
- CCDC6 | c.1166G>A p.G389E | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.083); catalogued as COSV54055688; called by muse, mutect2, varscan2
- CCDC60 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 56/168 reads (33%) | catalogued as COSV59541911; called by muse, mutect2, varscan2
- CCDC65 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 37/115 reads (32%) | catalogued as COSV57195005; called by muse, mutect2, varscan2
- CCDC7 | c.2481A>C p.E827D | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV56539479; called by muse, mutect2, varscan2
- CCDC7 | c.4028C>T p.S1343L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.988); catalogued as rs761341812, COSV56539494; called by muse, mutect2, varscan2
- CCDC70 | c.138T>G p.I46M | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.165); catalogued as COSV54429963; called by muse, mutect2, varscan2
- CCDC73 | c.2691A>C p.K897N | Missense Mutation (SNP) | VAF 63/190 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58796793; called by muse, mutect2, varscan2
- CCDC73 | c.1489A>C p.I497L | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV58796800; called by muse, mutect2, varscan2
- CCDC73 | c.1171G>C p.D391H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.825); catalogued as COSV58796810; called by muse, mutect2, varscan2
- CCDC80 | c.2431C>T p.R811C | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1489458675, COSV52814970; called by muse, mutect2, varscan2
- CCDC80 | c.308G>T p.R103I | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as COSV52815775; called by muse, mutect2, varscan2
- CCDC88A | c.3191C>T p.A1064V | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.475); catalogued as COSV55058776; called by muse, mutect2, varscan2
- CCDC88A | c.2597A>G p.N866S | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.175); catalogued as COSV55058793; called by muse, mutect2, varscan2
- CCDC88A | c.2056A>G p.T686A | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV55058810; called by muse, mutect2, varscan2
- CCDC88C | c.4074G>T p.E1358D | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66236282; called by muse, mutect2, varscan2
- CCDC88C | c.2381C>T p.A794V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV66236295; called by muse, mutect2, varscan2
- CCDC93 | c.128G>T p.R43I | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100099433, COSV60120519; called by muse, mutect2, varscan2
- CCDC96 | c.1465C>T p.R489W | Missense Mutation (SNP) | VAF 77/206 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59508397; called by muse, mutect2, varscan2
- CCK | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV58183613; called by muse, mutect2
- CCL19 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs199848815; called by muse, mutect2, varscan2
- CCL27 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV52404699; called by muse, mutect2, varscan2
- CCN6 | c.734G>A p.R245K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV57889020; called by muse, mutect2, varscan2
- CCNB1 | c.868C>G p.L290V | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV56509560; called by muse, varscan2
- CCNB1 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.364); catalogued as rs138386021; called by muse, varscan2
- CCNB3 | c.1468A>C p.I490L | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV52071436; called by muse, mutect2, varscan2
- CCNB3 | c.3392A>C p.K1131T | Missense Mutation (SNP) | VAF 55/77 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV52071446; called by muse, mutect2, varscan2
- CCNF | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs560665712, COSV53538831; called by muse, mutect2, varscan2
- CCNF | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs1222692813, COSV53538854; called by muse, mutect2, varscan2
- CCNT1 | c.299A>C p.K100T | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56063659; called by muse, mutect2, varscan2
- CCPG1 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51241099; called by muse, mutect2, varscan2
- CCR7 | c.384T>G p.F128L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55848912; called by muse, mutect2, varscan2
- CCR8 | c.148C>A p.L50I | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV58336939; called by muse, mutect2, varscan2
- CCR9 | c.887A>C p.D296A (on ENST00000357632 / NM_031200.3; = p.D284A on NM_006641.4) | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV62939986; called by muse, mutect2, varscan2
- CCT3 | c.1534A>G p.T512A | Missense Mutation (SNP) | VAF 63/115 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV55288191; called by muse, mutect2, varscan2
- CCT8L2 | c.1652A>C p.K551T | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.005); catalogued as COSV63461976; called by muse, mutect2, varscan2
- CCZ1B | c.913A>T p.T305S | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as COSV100367814; called by muse, mutect2, varscan2
- CD101 | c.1529A>C p.E510A | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV56717046; called by muse, mutect2, varscan2
- CD101 | c.2467A>C p.N823H | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV56717056; called by muse, mutect2, varscan2
- CD109 | c.4060-1G>A p.X1354_splice | Splice Site (SNP) | VAF 17/48 reads (35%) | catalogued as COSV54647324; called by muse, varscan2
- CD163L1 | c.1244G>C p.S415T | Missense Mutation (SNP) | VAF 68/214 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV58013372; called by muse, mutect2, varscan2
- CD19 | c.931C>A p.L311I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV61188154; called by muse, mutect2, varscan2
- CD19 | c.968G>T p.R323I | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61188162; called by muse, mutect2, varscan2
- CD1B | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 141/255 reads (55%) | catalogued as rs370440810; called by muse, mutect2, varscan2
- CD1D | c.134A>G p.D45G | Missense Mutation (SNP) | VAF 71/326 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV63808671; called by muse, mutect2, varscan2
- CD200R1L | c.184T>G p.L62V | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.232); catalogued as COSV68004007; called by muse, mutect2
- CD22 | c.1612G>T p.E538* | Nonsense Mutation (SNP) | VAF 60/88 reads (68%) | catalogued as COSV50050644; called by muse, mutect2, varscan2
- CD244 | c.569A>G p.D190G (on ENST00000368033 / NM_001166663.2; = p.D185G on NM_016382.4) | Missense Mutation (SNP) | VAF 105/214 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV59236872; called by muse, mutect2, varscan2
- CD247 | c.206A>G p.N69S | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.183); catalogued as COSV62977510; called by muse, mutect2, varscan2
- CD300LB | c.302T>C p.V101A | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV58725357; called by muse, mutect2, varscan2
- CD38 | c.881C>A p.S294* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as COSV56889129; called by muse, mutect2, varscan2
- CD4 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1555117895, COSV50589823; called by muse, mutect2, varscan2
- CD52 | c.79A>C p.N27H | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.307); catalogued as COSV57484950; called by muse, mutect2, varscan2
- CD55 | c.277T>C p.F93L | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV58576710; called by muse, mutect2, varscan2
- CD84 | c.486G>T p.K162N | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV60867365; called by muse, mutect2, varscan2
- CD96 | c.1143A>C p.E381D (on ENST00000283285 / NM_198196.3; = p.E365D on NM_005816.5) | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.043); catalogued as COSV51914384; called by muse, mutect2, varscan2
- CDC123 | c.695T>G p.F232C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55397116; called by muse, mutect2, varscan2
- CDC14B | c.1421G>T p.R474I | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.23); catalogued as COSV55786022; called by muse, mutect2, varscan2
- CDC14B | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs773237782, COSV55786041; called by muse, mutect2, varscan2
5,867 further variants in this file (4,382 protein-altering or splice-affecting, 1,341 silent, 144 other) are not listed here.
